Somatic mutation profile of tumor specimen TARGET-20-PASINN-09A (aliquot TARGET-20-PASINN-09A-02D) from TARGET case TARGET-20-PASINN, project TARGET-AML (Acute Myeloid Leukemia). Sex at birth: male; Vital status: Dead; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 3.6 years (1,330 days).
Specimen TARGET-20-PASINN-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 261fe30f-6732-4a4c-a4c9-a88629d917ba.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-20-PASINN-14A (Bone Marrow Normal), aliquot TARGET-20-PASINN-14A-02D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4af7e8ce-dd65-4914-b2a7-ff2f582c4faf

The open-access MAF lists 4 somatic variants for this specimen: 3 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 2, Silent 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BCOR | c.4376A>G p.N1459S (on ENST00000378444 / NM_001123385.2; = p.N1425S on NM_017745.6) | Missense Mutation (SNP) | VAF 26/41 reads (63%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.578); catalogued as rs199538037, COSV60698733; called by muse, mutect2, varscan2
- LAMA1 | c.7850C>T p.T2617M | Missense Mutation (SNP) | VAF 63/195 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.607); catalogued as rs751200271, COSV67533423; called by muse, mutect2, varscan2
- WT1 | c.1094_1097dup p.V367Sfs*7 | Frame Shift Ins (INS) | VAF 52/160 reads (33%) | catalogued as COSV100188405, COSV60067664, COSV60073144; called by mutect2, pindel, varscan2
- EVC | c.474C>A p.S158= | Silent (SNP) | VAF 38/121 reads (31%) | catalogued as COSV53830113; called by muse, mutect2, varscan2
